Surgical pathology report (de-identified scan), TCGA case TCGA-FE-A3PD, project TCGA-THCA (Thyroid Carcinoma), tissue source site Ohio State University, specimen TCGA-FE-A3PD-01A (Primary Tumor).

[page 1 of 3]
Page 1 of 3

Print this Page

Sex

Specimen Description

procurement date: - - -

Surgical Pathology Report

ICD-0-3

****Clinical History****
Clinical history: Thyroid cancer.

Path: carcinoma, papillary, follicular variant 8340/3
CQCF: carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9 lw 2/5/12

****Final Pathologic Diagnosis****

Pretracheal mass, biopsy:
Three Benign Lymph Nodes (0/3).

Left Thyroid Lobe, excision:
Papillary Thyroid Carcinoma, Follicular Variant see synoptic
report.
- Lymphocytic Thyroiditis.

Right Thyroid Lobe and Isthmus, excision:
- Lymphocytic Thyroiditis.
- Negative for Carcinoma.

****Addendum Report****
Addendum

Status: Signed Out

Immunohistology shows positive staining for TTF-1.
The immunohistochemical and/or in situ hybridization tests reported here,
except for those addressing Her-2Neu overexpression, have been developed
and their performance characteristics determined by the
Immunohistochemistry and Department of Pathology at [redacted] in the

[page 2 of 3]
*****Synoptic Report*****

SYNOPTIC REPORT FOR THYROID CANCER:

Procedure: total thyroidectomy
Tumor location: left lobe
Tumor size: 2.3 x 1.8 x 1.7 cm.
Histologic type: Papillary Thyroid Carcinoma, follicular variant
Tumor grade: low grade
Lymphatic/vascular invasion: present
Capsular invasion: absent
Tumor extent:
Confined to the thyroid: yes
Multifocal: no
Infiltration of adjacent structures: not seen
Lymph nodes:
Total number examined: three
Number positive: none
pTNM: T2 N0 Mx.

The above synoptic report complies, in slightly modified form, with the guidelines of the [redacted] for the reporting of cancer specimens

*****INTRAOPERATIVE CONSULTATION DIAGNOSIS:*****

[redacted] Pretracheal mass: (FROZEN SECTION PERFORMED)
- Benign.

[redacted] Left thyroid lobe: (FROZEN SECTION PERFORMED)
- Papillary carcinoma, follicular variant.

Examining pathologist: [redacted]

*****SPECIMEN(S) RECEIVED:*****

[redacted] Trachea, REG
Thyroid, REG
Thyroid, REG

*****GROSS DESCRIPTION:*****

The specimens are received in three properly labeled containers with the patient's name and accession number.

[redacted] The specimen is designated "pretracheal mass" and consists of a fragment of tissue measuring 0.9 x 0.5 x 0.2 cm. The tissue was previously submitted for frozen section and is now resubmitted for evaluation.

[redacted] The specimen is designated "left thyroid lobe" and was previously oriented as follows: One stitch = superior pole. Two stitches = inferior pole and consists of an 8.8 gram thyroid lobe that measures 3.8 x 2.7 x 1.8 cm. The thyroid lobe is inked black. On cut section there is a tan-yellow nodule that measures 2.3 x 1.8 x 1.7 cm. The tumor shows

[page 3 of 3]
infiltrative borders and is seen to infiltrate the thyroid capsule. The uninvolved surrounding thyroid parenchyma is beefy red-brown and unremarkable.

Summary of Cassettes: BF1, tumor, frozen section; B1, superior pole, shave; B2, inferior pole shave; B3-4, representative sections of tumor; B5, left lobe random section

The specimen is designated "right thyroid lobe" and is oriented as follows: One stitch = superior pole. Two stitches = inferior pole and consist of a 5.75 gram thyroid lobe that measures 4.3 x 3.2 x 0.7 cm. The thyroid lobe is inked black and the isthmus is inked green. On cut section, the thyroid parenchyma is beefy red-brown and unremarkable.

Summary of Cassettes: C1, superior pole, shave; C2, inferior pole, shave; C3, isthmus; C4-5, right lobe random sections

Lab Use Only: [REDACTED]

Gross description by: [REDACTED]

Top of Page

Source: NCI Genomic Data Commons file 65291aec-af67-43a6-8107-86cd47a45a3d (TCGA-FE-A3PD.F8EB4396-7186-41BA-B4BD-9BE38ED4B9E6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).